Somatic mutation profile of tumor specimen 0DOJXT from CCDI case PBCCLD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.8 years (6,152 days).
Specimen 0DOJXT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2602c8b0-7aa9-4d89-b2ea-49371ec71f0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOJUV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02b9f4c2-66dd-4f08-b60b-d1a51bb11a53

The open-access MAF lists 51 somatic variants for this specimen: 37 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 8, Nonsense Mutation 4, Intron 4, Frame Shift Del 3, Splice Site 2, 3'UTR 1, 5'UTR 1, In Frame Ins 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1745C>T p.S582L (on ENST00000281708 / NM_001349798.2; = p.S502L on NM_018315.5) | Missense Mutation (SNP) | VAF 214/614 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV104381731, COSV55890836; called by muse, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 229/574 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 205/666 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 348/845 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554898129, CM110132, COSV64288974, COSV64292774, COSV64296979; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PTEN | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 144/458 reads (31%) | hotspot (GDC flag); catalogued as rs121909231, CM971278, COSV64288687, COSV64297951; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADARB2 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 162/415 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs776987710; called by muse, mutect2, varscan2
- ANOS1 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 366/436 reads (84%) | SIFT tolerated (0.64); PolyPhen benign (0.062); catalogued as rs774940627, COSV52921411; called by muse, mutect2, varscan2
- DCTN1 | c.1927C>T p.R643* | Nonsense Mutation (SNP) | VAF 167/427 reads (39%) | catalogued as rs866457869, COSV62619563; called by muse, mutect2, varscan2
- ITGA6 | c.1898G>A p.R633H (on ENST00000442250; = p.R594H on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 256/798 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs754282661, COSV51226071; called by muse, mutect2, varscan2
- ITPR3 | c.5000G>A p.R1667Q | Missense Mutation (SNP) | VAF 189/501 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs751368153, COSV100968196, COSV65407219; called by muse, mutect2, varscan2
- LRP5 | c.3188G>A p.R1063H | Missense Mutation (SNP) | VAF 207/508 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs755269989, COSV53715070; called by muse, mutect2, varscan2
- LZTR1 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 20/640 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.938); catalogued as rs935736801, COSV53151511; called by muse, mutect2
- MATR3 | c.2160del p.I720Mfs*73 | Frame Shift Del (DEL) | VAF 241/613 reads (39%) | catalogued as COSV63080517; called by mutect2, varscan2
- MUC5B | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 143/362 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.335); catalogued as rs1390952963, COSV101500273; called by muse, mutect2, varscan2
- MYH1 | c.946G>A p.V316I | Missense Mutation (SNP) | VAF 234/683 reads (34%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as rs201099132, COSV56853800; called by muse, mutect2, varscan2
- PLIN5 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 89/265 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs553049950; called by muse, mutect2, varscan2
- PRR30 | c.1234G>A p.V412I | Missense Mutation (SNP) | VAF 99/286 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV99574416; called by muse, mutect2, varscan2
- RIC3 | c.326dup p.L109Ffs*9 | Frame Shift Ins (INS) | VAF 134/309 reads (43%) | catalogued as rs746684945; called by mutect2, varscan2
- SLC1A6 | c.205+3G>T | Splice Region (SNP) | VAF 155/390 reads (40%) | catalogued as rs976598865; called by muse, mutect2, varscan2
- SLCO6A1 | c.1811C>T p.T604M | Missense Mutation (SNP) | VAF 212/572 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs139495343, COSV65808002; called by muse, mutect2, varscan2
- TTN | c.7057+1G>A p.X2353_splice (on ENST00000591111; = p.X2307_splice on NM_003319.4) | Splice Site (SNP) | VAF 234/626 reads (37%) | catalogued as rs763909866, COSV59913969; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZC3HAV1 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 326/777 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1367089269, COSV99648088; called by muse, mutect2, varscan2
- ZCCHC14 | c.1250C>T p.S417L (on ENST00000268616; = p.S554L on NM_015144.3) | Missense Mutation (SNP) | VAF 32/537 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV51886842; called by muse, mutect2
- ATAT1 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 168/599 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- BCOR | c.4356_4363del p.A1453Tfs*5 (on ENST00000378444 / NM_001123385.2; = p.A1419Tfs*5 on NM_017745.6) | Frame Shift Del (DEL) | VAF 179/241 reads (74%) | called by mutect2, varscan2
- COP1 | c.1277+1G>A p.X426_splice | Splice Site (SNP) | VAF 375/438 reads (86%) | called by muse, mutect2, varscan2
- GRIA4 | c.2189T>G p.M730R | Missense Mutation (SNP) | VAF 34/596 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); called by muse, mutect2
- IWS1 | c.2333A>C p.Q778P | Missense Mutation (SNP) | VAF 33/711 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2
- IWS1 | c.1717G>T p.E573* | Nonsense Mutation (SNP) | VAF 179/459 reads (39%) | called by muse, mutect2, varscan2
- NFIA | c.454_455del p.K152Vfs*6 | Frame Shift Del (DEL) | VAF 126/480 reads (26%) | called by mutect2, varscan2
- NOTCH1 | c.1318_1320dup p.C440dup | In Frame Ins (INS) | VAF 134/398 reads (34%) | called by mutect2, varscan2
- OVCH1 | c.1593G>T p.L531F | Missense Mutation (SNP) | VAF 164/404 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SBNO2 | c.4042G>A p.E1348K | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SETD2 | c.1366C>T p.R456* | Nonsense Mutation (SNP) | VAF 247/573 reads (43%) | called by muse, mutect2, varscan2
- TTN | c.68958T>A p.D22986E (on ENST00000591111; = p.D15562E on NM_003319.4) | Missense Mutation (SNP) | VAF 245/656 reads (37%) | PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UGT1A8 | c.581T>C p.L194P | Missense Mutation (SNP) | VAF 212/646 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, varscan2
- UGT2B17 | c.1246G>T p.V416L | Missense Mutation (SNP) | VAF 225/745 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ADCY7 | c.1545C>T p.N515= | Silent (SNP) | VAF 179/479 reads (37%) | catalogued as rs144290211; called by muse, mutect2, varscan2
- AHNAK | c.11130C>T p.P3710= | Silent (SNP) | VAF 169/442 reads (38%) | called by muse, mutect2, varscan2
- FAT2 | c.2970G>A p.E990= | Silent (SNP) | VAF 131/459 reads (29%) | called by muse, mutect2, varscan2
- FLT3 | c.564C>T p.S188= | Silent (SNP) | VAF 301/753 reads (40%) | catalogued as rs774682624, COSV54068526, COSV99610282; called by muse, mutect2, varscan2
- FTCD | c.120A>G p.A40= | Silent (SNP) | VAF 226/553 reads (41%) | called by muse, mutect2, varscan2
- PROKR2 | c.294C>T p.S98= | Silent (SNP) | VAF 149/323 reads (46%) | catalogued as rs146061254; called by muse, mutect2, varscan2
- PSD2 | c.1507C>T p.L503= | Silent (SNP) | VAF 201/623 reads (32%) | called by muse, mutect2, varscan2
- PZP | c.330G>A p.T110= | Silent (SNP) | VAF 266/665 reads (40%) | catalogued as rs767650975, COSV54359975; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.*119G>A | 3'UTR (SNP) | VAF 104/272 reads (38%) | called by muse, mutect2, varscan2
- ARHGEF12 | c.142+57A>T | Intron (SNP) | VAF 18/364 reads (5%) | called by muse, mutect2
- C3orf49 | c.849+6284C>T | Intron (SNP) | VAF 51/139 reads (37%) | catalogued as rs559010509; called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 20/200 reads (10%) | called by muse, varscan2
- SPAG16 | c.832+90_832+93del | Intron (DEL) | VAF 66/164 reads (40%) | catalogued as COSV55988355; called by mutect2, varscan2
- TNFSF10 | c.133-3326C>T | Intron (SNP) | VAF 67/166 reads (40%) | catalogued as rs930570211; called by muse, mutect2, varscan2
